Somatic mutation profile of tumor specimen TCGA-A2-A25C-01A (aliquot TCGA-A2-A25C-01A-11D-A167-09) from TCGA case TCGA-A2-A25C, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 50.7 years (18,508 days).
Specimen TCGA-A2-A25C-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 16d270e3-d61c-4a43-9cd4-a59ed400f9e0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A2-A25C-10A (Blood Derived Normal), aliquot TCGA-A2-A25C-10A-01D-A167-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/10c1c01f-d95c-4ee0-b733-54fa16133bf1

The open-access MAF lists 30 somatic variants for this specimen: 25 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 4, Splice Site 2, Nonsense Mutation 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 15/38 reads (39%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AKAP7 | c.952G>A p.E318K (on ENST00000431975 / NM_016377.4; = p.E51K on NM_004842.4) | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV53834803; called by muse, mutect2, varscan2
- CP | c.204G>T p.K68N | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52830305; called by muse, mutect2, varscan2
- CPE | c.739C>T p.L247F | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.342); catalogued as COSV68580072; called by muse, mutect2, varscan2
- DPY19L2 | c.159G>C p.R53S | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.003); catalogued as rs1316200234, COSV100116675; called by muse, mutect2
- EEF1A1 | c.20A>G p.H7R | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.642); catalogued as COSV58549504; called by muse, mutect2, varscan2
- GRHL2 | c.1129G>T p.D377Y | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99306656; called by muse, mutect2
- HMCN1 | c.3378-1G>C p.X1126_splice | Splice Site (SNP) | VAF 25/128 reads (20%) | catalogued as COSV54897080; called by muse, mutect2, varscan2
- IFT52 | c.1115A>G p.N372S | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.493); catalogued as rs1367910461, COSV100887584; called by muse, mutect2
- KCNK13 | c.486G>T p.Q162H | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV56412797; called by muse, mutect2, varscan2
- KCNK9 | c.29C>T p.S10F | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as rs764960417, COSV57280991; called by muse, varscan2
- MCTP1 | c.903A>G p.I301M | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs772947808, COSV56513715; called by muse, mutect2, varscan2
- MED23 | c.2149C>T p.Q717* | Nonsense Mutation (SNP) | VAF 17/30 reads (57%) | catalogued as COSV63431063; called by muse, mutect2, varscan2
- NCAM2 | c.2081C>T p.T694M | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.642); catalogued as COSV53055705; called by muse, mutect2, varscan2
- OR1J1 | c.34T>C p.F12L | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV52238386; called by muse, mutect2, varscan2
- OR8A1 | c.215G>A p.C72Y | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as COSV52508473; called by muse, mutect2, varscan2
- PCDHGA11 | c.626A>G p.H209R | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.781); catalogued as COSV53938326, COSV54044675; called by muse, mutect2, varscan2
- PCNX1 | c.2219C>A p.A740D | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV53093924; called by muse, mutect2, varscan2
- PCOLCE | c.1102G>T p.G368* | Nonsense Mutation (SNP) | VAF 3/47 reads (6%) | catalogued as COSV99774921; called by muse, mutect2
- RNF6 | c.1469G>A p.G490E | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777775247, COSV60418733; called by muse, mutect2, varscan2
- TAB2 | c.1276G>T p.V426L | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV99644733; called by muse, mutect2
- TTC23 | c.581+1G>T p.X194_splice | Splice Site (SNP) | VAF 6/108 reads (6%) | catalogued as COSV100018622; called by muse, mutect2
- TTN | c.50889G>T p.K16963N (on ENST00000591111; = p.K9539N on NM_003319.4) | Missense Mutation (SNP) | VAF 4/29 reads (14%) | PolyPhen benign (0.189); catalogued as COSV60022094, COSV60211366; called by muse, mutect2, varscan2
- UBTF | c.246C>A p.F82L | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.164); catalogued as COSV100255881; called by muse, mutect2
- WDR4 | c.504G>T p.K168N | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57733356; called by muse, mutect2
- CD1D | c.195C>A p.V65= | Silent (SNP) | VAF 3/27 reads (11%) | catalogued as COSV100939585; called by muse, mutect2
- DENND11 | c.861C>T p.G287= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as rs1323426191, COSV72097649; called by muse, mutect2, varscan2
- ENAH | c.600G>A p.R200= | Silent (SNP) | VAF 37/124 reads (30%) | catalogued as COSV52867569; called by muse, mutect2, varscan2
- ZNF473 | c.876T>C p.C292= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as COSV54522998; called by muse, mutect2, varscan2
- PLXNA4 | c.1371+4421A>T | Intron (SNP) | VAF 8/34 reads (24%) | catalogued as COSV58122030; called by muse, mutect2, varscan2
